Gene-level copy-number profile of tumor specimen TCGA-VQ-A8PK-01A from TCGA case TCGA-VQ-A8PK, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 58.6 years (21,419 days).
Specimen TCGA-VQ-A8PK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.1bb7ea1c-f778-42eb-a037-bfafb326252c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VQ-A8PK-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 816 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c24b26e3-5f1b-41fe-846d-05d7fa1c0367

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 107; copy number 1: 33,223; copy number 2: 21,773; copy number 3: 3,972; copy number 4: 240; copy number 5: 46; copy number 6: 105; copy number 7: 107; copy number 8: 19; copy number 9: 63; copy number 10: 54; copy number 12: 98.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VQ-A8PK-01A-12D-A40Z-01): tumor purity 0.65, ploidy 1.6, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 105 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:186,486,253–186,695,287, 4 genes: ZC3H15, DPRXP1, ITGAV, AC017101.1.
- chr4:49,096–384,868, 16 genes (within-gene range 0–2): BNIP3P41, ZNF595, AC253576.1, ZNF718, AC253576.2, AC108475.1, ZNF876P, AC079140.3, AC079140.5, ZNF732, AC079140.6, AC079140.4, ZNF141, AC079140.1, AC079140.2, MIR571.
- chr4:165,361,194–167,234,796, 14 genes (within-gene range 0–3): CPE, MIR578, HADHAP1, SCGB1D5P, NOL8P1, AC080079.2, AC080079.1, LINC01179, TLL1, RNA5SP170, Y_RNA, AC097487.1, SPOCK3, RNA5SP171.
- chr6:2,617,144–2,640,001, 2 genes: LINC02521, LINC01600.
- chr6:20,722,328–20,800,694, 2 genes: AL035090.1, AL513188.1.
- chr8:90,058,608–90,095,475, 1 gene: CALB1.
- chr9:26,642,697–26,796,304, 3 genes: AL442639.1, AL451137.2, AL451137.1.
- chr10:87,751,512–87,994,695, 8 genes (within-gene range 0–1): ATAD1, CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2, RPL11P3, AC063965.1.
- chr12:120,710,458–121,191,518, 22 genes: UNC119B, AC069234.3, MIR4700, ACADS, AC069234.1, SPPL3, ARF1P2, AC069214.1, CLIC1P1, RPL12P33, HNF1A-AS1, HNF1A, C12orf43, OASL, OASL2P, AC079602.2, AC079602.3, SNORA70, AC079602.1, P2RX7, AC069209.2, AC069209.1.
- chr12:129,170,092–129,170,238, 1 gene: AC107033.1.
- chr19:94,062–376,026, 18 genes: OR4G3P, OR4G1P, OR4F17, WBP1LP11, OR4F8P, AC092192.1, SEPTIN14P19, CICP19, AC092299.1, AC010507.1, LINC01002, AC010507.2, RNU6-1076P, AC016588.2, PLPP2, MIER2, AC016588.1, THEG.
- chr20:14,757,563–15,280,873, 6 genes: RPS10P2, MACROD2-AS1, AL138808.1, RNU6-1159P, RNU6-115P, RNA5SP475.
- chr22:50,674,415–50,801,309, 8 genes (within-gene range 0–6): SHANK3, RNU6-409P, AC000036.1, ACR, AC002056.2, AC002056.1, RPL23AP82, RABL2B.

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 4,704 genes in 57 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,181,794–2,530,263, 16 genes, copy number 3: PRKCZ-AS1, FAAP20, AL590822.1, SKI, AL590822.3, MORN1, AL589739.1, AL513477.1, AL513477.2, RER1, PEX10, PLCH2, AL139246.1, AL139246.4, PANK4, HES5.
- chr1:7,784,320–8,344,167, 19 genes, copy number 3 (within-gene range 2–3): PER3, Z98884.1, UTS2, TNFRSF9, AL009183.1, PARK7, Y_RNA, AL034417.4, AL034417.3, ERRFI1, AL034417.2, AL034417.1, AL358876.1, LINC01714, RNU1-7P, AL358876.2, RNU6-991P, SLC45A1, Y_RNA.
- chr1:153,890,595–155,050,930, 66 genes, copy number 4 (within-gene range 2–4) (broad region; genes not listed).
- chr1:206,470,476–208,270,667, 54 genes, copy number 3–5: IKBKE, MIR6769B, C1orf147, AC244034.2, RASSF5, AC244034.1, AC244034.3, EIF2D, DYRK3-AS1, DYRK3, MAPKAPK2, AL591846.1, Y_RNA, IL10, IL19, IL20, IL24, FCMR, AC098935.2, AC098935.1, PIGR, FCAMR, C1orf116, PFKFB2, YOD1, C4BPB, C4BPA, AL445493.1, C4BPAP1, AL445493.2, C4BPAP2, AL596218.1, CD55, AL391597.1, CR2, CR1, AL137789.1, CR1L, CD46P1, CDCA4P3, RNA5SP534, AL137789.2, CD46, CDCA4P4, MIR29B2CHG, MIR29C, MIR29B2, CD34, AL356275.1, LINC02767, PLXNA2, AL590138.1, AL606753.1, AL606753.2.
- chr1:233,614,106–235,104,609, 43 genes, copy number 3: KCNK1, MIR4427, AL357972.1, AL663058.1, AL663058.2, AL713868.1, SLC35F3, RAC1P7, AL122008.3, AL122008.1, SLC35F3-AS1, AL122008.2, MIR4671, AL355472.1, AL355472.2, AL355472.3, COA6-AS1, COA6, TARBP1, LINC01354, AL161640.2, AL161640.3, AL161640.1, U8, IRF2BP2, AL160408.2, LINC00184, AL160408.5, AL160408.1, AL160408.4, AL160408.3, AL160408.6, LINC01132, PP2672, AL391832.4, RNY4P16, RN7SL668P, AL391832.1, AL391832.2, AL391832.3, LINC01348, AL732292.1, AL732292.2.
- chr2:173,075,435–173,486,362, 8 genes, copy number 3: MAP3K20, MAP3K20-AS1, RPS2P18, AC092573.1, CDCA7, JPT1P1, CBY1P1, PPIAP66.
- chr2:187,464,230–191,246,172, 58 genes, copy number 3: TFPI, LINC01090, ST13P2, AC104131.1, RNA5SP114, GULP1, MIR561, AC092598.1, DIRC1, COL3A1, MIR1245A, MIR1245B, MIR3606, COL5A2, AC133106.1, MIR3129, KRT18P19, WDR75, KDM3AP1, AC013439.1, SLC40A1, AC012488.1, ASNSD1, ASDURF, AC012488.2, ANKAR, OSGEPL1, OSGEPL1-AS1, AC013468.1, ORMDL1, PMS1, C2orf88, TERF1P6, HNRNPCP2, RNF11P1, MSTN, HIBCH, INPP1, MFSD6, AC093388.1, NEMP2, AC108047.1, RN7SKP179, AC006460.2, NAB1, AC006460.1, AC005540.1, GLS, STAT1, RAB1AP1, AC067945.1, AC067945.2, STAT4, AC067945.3, RNU6-959P, AC079777.1, HMGB1P27, AC092614.1.
- chr3:91,356,755–183,555,706, 1,448 genes, copy number 3–4 (within-gene range 2–4) (broad region; genes not listed).
- chr4:132,836,772–165,343,164, 459 genes, copy number 3 (broad region; genes not listed).
- chr4:167,306,910–190,092,279, 321 genes, copy number 3–4 (broad region; genes not listed).
- chr6:38,675,925–49,636,839, 244 genes, copy number 3 (within-gene range 3–5) (broad region; genes not listed).
- chr6:131,573,966–132,169,374, 19 genes, copy number 3: MED23, ENPP3, RNU4-18P, OR2A4, CTAGE9, AC005587.1, MIR548H5, ENPP1, SELENOKP2, RN7SKP245, AL139805.1, AL117378.1, AL117378.2, CCN2, AL133346.1, AL021408.1, MIR548AJ1, AL021408.2, LINC01013.
- chr6:159,669,069–167,997,110, 133 genes, copy number 3–4 (within-gene range 1–4) (broad region; genes not listed).
- chr7:99,173,574–101,629,296, 143 genes, copy number 3 (broad region; genes not listed).
- chr8:112,222,928–145,066,685, 519 genes, copy number 3–4 (within-gene range 2–4) (broad region; genes not listed).
- chr12:10,332,861–10,723,323, 17 genes, copy number 3: LINC02617, LINC02598, KLRK1-AS1, KLRK1, KLRC4-KLRK1, KLRC4, AC068775.1, KLRC3, KLRC2, KLRC1, EIF2S3B, SLC25A39P2, LINC02446, KLRA1P, MAGOHB, STYK1, YBX3.
- chr12:16,989,126–17,400,914, 8 genes, copy number 7: SKP1P2, EEF1A1P16, AC092793.1, RNU6-837P, AC092110.1, RPL7P40, PSMC1P8, TIMM17BP1.
- chr12:21,468,910–31,959,316, 204 genes, copy number 6–12 (broad region; genes not listed).
- chr13:52,219,344–53,202,753, 23 genes, copy number 3: TPTE2P2, LINC02333, THSD1, RNY4P24, VPS36, AL359513.1, CKAP2, LINC00345, AL137058.1, AL137058.3, AL137058.2, MRPS31P4, HNRNPA1L2, SUGT1-DT, SUGT1, CNMD, MIR759, PPIAP26, PCDH8, OLFM4, LINC01065, AL136359.1, PCDH8P1.
- chr14:96,019,484–96,489,427, 16 genes, copy number 3: AL137190.1, C14orf132, BDKRB2, AL355102.2, AL355102.1, CKS1BP1, AL355102.5, BDKRB1, AL355102.4, AL355102.3, ATG2B, GSKIP, RNU2-33P, AK7, PEBP1P1, RPL23AP10.
- chr15:29,699,367–30,883,231, 56 genes, copy number 3: TJP1, AC022613.3, HMGN2P5, AC022613.2, NCAPGP2, AC111152.2, SYNGR2P1, AC111152.1, GOLGA8J, RN7SL673P, DNM1P28, ULK4P3, U8, GOLGA8T, RN7SL469P, DNM1P30, AC120045.2, AC120045.1, LINC02249, AC135731.1, RNU6-17P, AC135731.2, AC019322.4, Y_RNA, CHRFAM7A, AC019322.1, U8, AC019322.3, GOLGA8R, RN7SL196P, AC019322.2, AC127502.1, AC127502.2, AC127502.3, AC026150.2, AC026150.1, GOLGA8Q, RN7SL796P, DNM1P50, ULK4P2, U8, GOLGA8H, AC026150.3, RN7SL628P, AC091057.3, AC091057.2, ARHGAP11B, AC091057.5, AC091057.6, AC091057.1, Y_RNA, AC091057.4, GOLGA8UP, RN7SL82P, HERC2P10, AC087481.1.
- chr15:31,765,743–35,011,191, 90 genes, copy number 3 (broad region; genes not listed).
- chr15:35,546,154–37,254,952, 23 genes, copy number 7 (within-gene range 3–7): DPH6-DT, AC068867.1, LINC02853, MIR4510, AC021351.1, AC087516.1, AC087516.2, COX6CP4, CDIN1, AC103988.1, LARP4P, TPST2P1, AC013640.1, CSNK1A1P1, U3, AC018563.1, MEIS2, MIR8063, Y_RNA, AC078909.1, AC078909.2, Metazoa_SRP, AC087283.1.
- chr15:69,160,584–70,854,157, 35 genes, copy number 6–7 (within-gene range 1–7): GLCE, AC026992.2, AC026992.1, PAQR5, AC027237.4, AC027237.3, Y_RNA, KIF23, AC027237.1, RPLP1, U3, AC027237.2, DRAIC, AC100826.1, GEMIN8P1, AC021818.1, TLE3, MIR629, RNU6-745P, AC026583.1, AC048383.1, LINC02205, AC009434.1, LINC02204, AC087699.1, SALRNA3, SALRNA2, UACA, AC009269.2, AC009269.5, AC009269.3, AC009269.1, RPL29P30, LARP6, AC009269.4.
- chr15:75,415,249–76,344,365, 39 genes, copy number 9: AC105137.1, AC105137.2, PTPN9, AC105036.2, AC105036.1, AC105036.3, SNUPN, AC105020.3, AC105020.2, IMP3, AC105020.6, AC105020.5, SNX33, CSPG4, AC105020.4, AC105020.1, ODF3L1, DNM1P35, AC019294.2, PPIAP47, AC019294.3, MIR4313, AC019294.1, RN7SL319P, DNM1P49, UBE2Q2, RN7SL510P, FBXO22, NRG4, AC027104.1, TMEM266, AC091100.1, ETFA, Metazoa_SRP, TYRO3P, AC027243.3, ISL2, AC027243.1, AC027243.2.
- chr15:94,033,658–97,432,094, 50 genes, copy number 5–9 (within-gene range 2–9): AC104390.1, H3P40, MCTP2, AC135626.1, AC135626.2, AC009432.2, LINC02852, AC009432.1, AC022308.1, AC087633.2, AC107976.1, AC087633.1, AC087636.1, LINC01197, AC104260.1, AC104260.2, AC104260.3, LINC00924, AC027013.1, AC015574.1, RNU2-3P, AC012409.2, AC024337.1, AC024337.2, NR2F2-AS1, AC012409.5, AC012409.3, AC012409.1, AC012409.4, LINC02157, AC016251.1, NR2F2, MIR1469, AC103746.1, AC087477.2, TUBAP12, AC087477.5, AC087477.3, PGAM1P12, AC087477.1, AC087477.4, RN7SKP254, Metazoa_SRP, AC110588.1, FAM149B1P1, SPATA8-AS1, SPATA8, RN7SKP181, LINC02253, AC020704.1.
- chr15:101,043,716–101,295,282, 8 genes, copy number 5: AC090907.1, AC090907.2, AC090907.3, AC019254.2, AC019254.1, CHSY1, SELENOS, SNRPA1.
- chr17:1,241,939–1,900,082, 27 genes, copy number 3: AC144836.1, BHLHA9, TRARG1, YWHAE, AC032044.2, CRK, AC032044.1, MYO1C, INPP5K, PITPNA-AS1, PITPNA, SLC43A2, RN7SL105P, SCARF1, RILP, PRPF8, AC130343.3, TLCD2, MIR22HG, MIR22, WDR81, AC130343.1, SERPINF2, SERPINF1, SMYD4, RPA1, AC130689.1.
- chr17:3,472,374–4,268,430, 32 genes, copy number 3 (within-gene range 1–3): ASPA, TRPV3, TRPV1, AC027796.5, AC027796.3, AC027796.1, SHPK, AC027796.2, CTNS, AC027796.4, TAX1BP3, P2RX5-TAX1BP3, AC132942.1, EMC6, P2RX5, ITGAE, AC116914.2, HASPIN, AC116914.1, NCBP3, CAMKK1, P2RX1, ATP2A3, LINC01975, ZZEF1, RNA5SP434, CYB5D2, ANKFY1, AC087292.1, Y_RNA, RYKP1, AC087742.1.
- chr17:36,591,879–36,936,670, 6 genes, copy number 3 (within-gene range 2–3): DHRS11, MRM1, AC243830.2, AC243830.3, AC243830.1, LHX1-DT.
- chr18:2,847,006–4,455,307, 36 genes, copy number 3 (within-gene range 2–3): EMILIN2, LPIN2, AP000919.3, CHORDC1P4, AP000919.1, AP000919.2, SNRPCP4, AP005431.1, SNORA70, MYOM1, RNU7-25P, AP005329.2, AP005329.3, MYL12A, AP005329.1, MYL12B, AP001025.1, LINC01895, RPL31P59, IGLJCOR18, RPL21P127, TGIF1, BOD1P1, GAPLINC, DLGAP1, RN7SL39P, AP002472.1, DLGAP1-AS1, DLGAP1-AS2, AP002478.1, AP002478.2, DLGAP1-AS3, MIR6718, RNU6-831P, DLGAP1-AS4, GAPDHP66.
- chr18:6,374,361–11,390,729, 105 genes, copy number 3–4 (broad region; genes not listed).
- chr18:14,222,008–15,330,282, 42 genes, copy number 4: RHOT1P1, AP005212.4, AP005212.2, CYP4F35P, AP005212.3, AP005212.1, TERF1P2, FEM1AP2, AP006261.1, LONRF2P1, CXADRP3, GRAMD4P7, POTEC, RNU6-1021P, OR4K7P, OR4K8P, SNX19P3, VN1R74P, GTF2IP8, ANKRD30B, RNU6-1210P, AP006565.1, MIR3156-2, LINC01906, FGF7P1, AP005121.1, LINC01443, LINC01444, AP005121.2, AP005242.4, AP005242.2, AP005242.3, AP005242.1, AP005242.5, AP005901.2, AP005901.6, AP005901.5, AP005901.3, BNIP3P3, AP005901.4, AP005901.1, RNU6-721P.
- chr19:27,638,483–30,228,715, 63 genes, copy number 6–12 (broad region; genes not listed).
- chr20:3,667,965–3,929,882, 16 genes, copy number 4: ADAM33, SIGLEC1, HSPA12B, C20orf27, SPEF1, CENPB, CDC25B, LINC01730, AL109804.1, AP5S1, MAVS, PANK2-AS1, PANK2, MIR103A2, MIR103B2, AL031670.1.
- chr20:53,255,979–54,070,594, 15 genes, copy number 3 (within-gene range 2–3): AL109930.1, AL354993.1, PPIAP10, AL354993.2, Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC005914.1, AC006076.1, SUMO1P1, BCAS1, AC005220.1, MIR4756.
- chr22:20,917,407–20,999,032, 6 genes, copy number 3 (within-gene range 1–3): CRKL, LINC01637, AIFM3, AC002470.2, AC002470.1, LZTR1.
- chr22:29,387,909–30,907,824, 66 genes, copy number 3 (within-gene range 1–3) (broad region; genes not listed).
- chr22:35,066,136–36,267,530, 40 genes, copy number 3: ISX, LINC01399, Z99755.2, Z99755.1, RNU7-167P, HMGXB4, AL008635.1, TOM1, MIR3909, MIR6069, Z82244.2, Z82244.1, HMOX1, MCM5, AL022334.1, AL022334.2, RASD2, MB, AL049747.1, APOL6, AL049748.1, MRPS16P3, APOL5, RBFOX2, NDUFA9P1, Z82217.1, Z95114.4, Z95114.1, Z95114.2, Z95114.3, APOL3, MTCO1P20, MTCO2P20, MTATP6P20, MTCO3P20, MTCYBP34, MTND1P10, APOL4, APOL2, APOL1.
- chr22:48,044,710–50,674,174, 87 genes, copy number 3–10 (within-gene range 3–13) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 30,804. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
